Somatic mutation profile of tumor specimen TCGA-AA-3860-01A (aliquot TCGA-AA-3860-01A-02W-0900-09) from TCGA case TCGA-AA-3860, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 53.2 years (19,449 days).
Specimen TCGA-AA-3860-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5ecb5b9-f00d-4d32-a3bd-42f8a168032c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3860-10A (Blood Derived Normal), aliquot TCGA-AA-3860-10A-01W-0902-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48a5f19e-ae8b-4055-a5ff-961601aad512

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 16, Frame Shift Del 3, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4012C>T p.Q1338* | Nonsense Mutation (SNP) | VAF 88/190 reads (46%) | hotspot (GDC flag); catalogued as rs121913327, CM930029, COSV57325971; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGTR1 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62560486; called by muse, mutect2
- ANKEF1 | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65692723; called by muse, mutect2, varscan2
- APC | c.704T>A p.L235* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as CM106350, COSV57355134, COSV57361797; called by muse, mutect2, varscan2
- BCAT1 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99678294; called by muse, mutect2
- CACNA1G | c.3721C>T p.R1241* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV61730999; called by muse, mutect2, varscan2
- CCNA1 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs749179710, COSV55222387; called by muse, mutect2, varscan2
- CD2AP | c.1153C>G p.P385A | Missense Mutation (SNP) | VAF 263/793 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63761409; called by muse, mutect2, varscan2
- CELSR2 | c.7615A>G p.I2539V | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV54774536; called by muse, mutect2, varscan2
- CFAP251 | c.364T>A p.S122T | Missense Mutation (SNP) | VAF 110/311 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.05); catalogued as COSV55839868; called by muse, mutect2, varscan2
- COL14A1 | c.3847C>T p.P1283S | Missense Mutation (SNP) | VAF 96/254 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1168553638, COSV52858839; called by muse, mutect2, varscan2
- CRB1 | c.2291G>A p.R764H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.708); catalogued as rs375040930, CM130791; ClinVar: uncertain significance; called by muse, mutect2
- CYP2F1 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as rs768113626, COSV100462602; called by muse, mutect2, varscan2
- ERCC6L | c.2195G>A p.R732K | Missense Mutation (SNP) | VAF 247/604 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV57821182; called by muse, mutect2, varscan2
- FAT2 | c.4809C>G p.F1603L | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55822903; called by muse, mutect2, varscan2
- FOXK2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV58879919; called by muse, mutect2, varscan2
- FOXP1 | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV59545815; called by muse, mutect2, varscan2
- GANAB | c.1507T>G p.W503G | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100647913; called by muse, mutect2, varscan2
- IFT88 | c.645G>C p.Q215H (on ENST00000319980 / NM_001318493.2; = p.Q206H on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60674644; called by muse, mutect2, varscan2
- LPCAT1 | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as COSV99358839; called by muse, mutect2, varscan2
- LYN | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV72923571; called by muse, mutect2, varscan2
- MIA3 | c.4129C>A p.L1377I | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100484884; called by muse, mutect2
- MUC16 | c.37855C>T p.R12619C | Missense Mutation (SNP) | VAF 215/658 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs765697877, COSV67444013; called by muse, mutect2, varscan2
- NLRP13 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs145312636; called by muse, mutect2, varscan2
- NOL4 | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52351354; called by muse, mutect2, varscan2
- PATE1 | c.101T>G p.V34G | Missense Mutation (SNP) | VAF 19/335 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV59825295, COSV99986101; called by muse, mutect2
- PCDHB13 | c.1160A>C p.Q387P | Missense Mutation (SNP) | VAF 149/423 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as COSV53398026; called by muse, mutect2, varscan2
- PMFBP1 | c.2795G>A p.S932N (on ENST00000537465; = p.S927N on NM_031293.3) | Missense Mutation (SNP) | VAF 107/167 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1274249188, COSV52826487; called by muse, mutect2, varscan2
- RABEP2 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV62868313; called by muse, mutect2, varscan2
- REG1A | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1446084582, COSV52069820; called by muse, mutect2, varscan2
- RTL3 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as COSV58184585; called by muse, mutect2, varscan2
- SRCAP | c.4546T>G p.S1516A | Missense Mutation (SNP) | VAF 170/383 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV52675454; called by muse, mutect2, varscan2
- TANC1 | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV55090749; called by muse, mutect2, varscan2
- TP53 | c.179del p.P60Qfs*63 | Frame Shift Del (DEL) | VAF 71/212 reads (33%) | catalogued as COSV52908942, COSV53348579, COSV53683260; called by mutect2, pindel, varscan2
- ZC3HC1 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61298860; called by muse, mutect2, varscan2
- ZFP91 | c.1420G>C p.D474H | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV60160101; called by muse, mutect2, varscan2
- SF3A3 | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 5/117 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- SMG8 | c.406_423del p.S136_Y141del | In Frame Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel
- TP53 | c.839_857del p.R280Kfs*59 | Frame Shift Del (DEL) | VAF 42/115 reads (37%) | called by mutect2, pindel, varscan2
- TRIM71 | c.1224del p.N409Tfs*20 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- ZRANB1 | c.1798dup p.R600Pfs*6 | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | called by mutect2, pindel
- AFF2 | c.1800C>A p.P600= | Silent (SNP) | VAF 258/459 reads (56%) | catalogued as COSV53995009; called by muse, mutect2, varscan2
- CEP95 | c.873C>T p.A291= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs1555678311, COSV73609430; called by muse, mutect2
- CLGN | c.1191C>T p.F397= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs76550209, COSV57773825; called by mutect2, varscan2
- COL7A1 | c.3558T>C p.N1186= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as COSV60397354; called by muse, mutect2, varscan2
- ENOSF1 | c.306T>A p.I102= (on ENST00000340116 / NM_001354066.2; = p.I54= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV51893606; called by muse, mutect2, varscan2
- GNA14 | c.798T>A p.I266= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV100502681; called by muse, mutect2
- KCNT2 | c.2427C>T p.A809= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs1351563539, COSV54088387, COSV54089580; called by muse, mutect2, varscan2
- KIT | c.276C>T p.T92= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs373066995, COSV99853634; called by muse, mutect2, varscan2
- NELL2 | c.738T>C p.D246= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV61578079; called by muse, mutect2, varscan2
- PCDHB6 | c.816G>A p.S272= | Silent (SNP) | VAF 92/225 reads (41%) | catalogued as rs1463000183, COSV50693020, COSV50728335; called by muse, mutect2, varscan2
- PGK2 | c.930C>A p.G310= | Silent (SNP) | VAF 21/380 reads (6%) | catalogued as COSV100505380; called by muse, mutect2
- SLC12A1 | c.1326C>T p.T442= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs769836162, COSV66793437; called by muse, mutect2, varscan2
- SP3 | c.1503G>A p.A501= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as rs189281761; called by muse, mutect2, varscan2
- TEX29 | c.315G>A p.A105= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs771364689, COSV52095745; called by muse, mutect2, varscan2
- TMEM81 | c.276C>T p.F92= | Silent (SNP) | VAF 11/234 reads (5%) | catalogued as COSV99196765, COSV99196861; called by muse, mutect2
- ZAN | c.4050G>A p.S1350= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs573564140, COSV61807252; called by muse, mutect2, varscan2
- TTN | c.10360+1348C>T | Intron (SNP) | VAF 107/247 reads (43%) | catalogued as rs764724389, COSV59895484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
